Somatic mutation profile of tumor specimen C3L-06766-01 (aliquot CPT0393480006) from CPTAC case C3L-06766, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.0 years (18,266 days).
Specimen C3L-06766-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc7bb37-e4ca-473b-bdd5-63c45c143f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06766-31 (Blood Derived Normal), aliquot CPT0390790005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e59f0a7-5ffe-4eb8-a472-49725934df89

The open-access MAF lists 141 somatic variants for this specimen: 103 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 32, Nonsense Mutation 7, 3'UTR 3, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Splice Region 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 95/379 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- FBLN5 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 28/367 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs864309526, CM113495, COSV50907168; ClinVar: likely pathogenic; called by muse, mutect2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 30/244 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.8401C>T p.R2801* | Nonsense Mutation (SNP) | VAF 36/340 reads (11%) | catalogued as rs1555191203, CM138446, COSV56410607; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 40/318 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/270 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WDR26 | c.1537G>A p.D513N (on ENST00000414423 / NM_001379403.1; = p.D413N on NM_025160.7) | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as rs1553354952; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA7 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs773749142; called by muse, mutect2, varscan2
- ACAP3 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 87/427 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs538976454; called by muse, mutect2, varscan2
- CALY | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs756598673; called by muse, mutect2, varscan2
- CNTNAP5 | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs969802074, COSV101443060, COSV70502340; called by muse, mutect2
- DAAM2 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764394245, COSV51421668; called by muse, mutect2
- DNMT3B | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1357390175, COSV52424874; called by muse, mutect2
- DTX4 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304854124; called by muse, mutect2, varscan2
- EDNRB | c.1163G>A p.C388Y (on ENST00000377211 / NM_001201397.1; = p.C298Y on NM_000115.5) | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV57525591; called by muse, mutect2
- EEFSEC | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 57/495 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773008456, COSV54621321; called by muse, mutect2, varscan2
- F7 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as CM090300; called by muse, mutect2
- GRM1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51117094; called by muse, varscan2
- IRS1 | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 44/477 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as rs752902060, COSV59334482, COSV59336549; called by muse, mutect2, varscan2
- KCNMB1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs773550380, COSV51131735; called by muse, mutect2
- KCNV2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 52/566 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs201520619; called by muse, mutect2
- KLHDC7A | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1367227097; called by muse, mutect2, varscan2
- KLHL5 | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 35/391 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1386693190; called by muse, mutect2
- LHX8 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 20/578 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1371048574; called by muse, mutect2
- LILRA5 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100006710; called by muse, mutect2, varscan2
- LRP1B | c.2577A>C p.Q859H | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63341545, COSV63341769; called by muse, mutect2
- LRP2 | c.13369G>A p.A4457T | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1485913090; called by muse, mutect2
- LRRTM4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs770333447, COSV69140702, COSV69142462; called by muse, mutect2
- MADD | c.1366del p.L456Ffs*66 | Frame Shift Del (DEL) | VAF 36/311 reads (12%) | catalogued as COSV60626622; called by mutect2, pindel
- MPO | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs764426896; called by muse, mutect2
- MTMR2 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100656825; called by muse, mutect2
- NAV3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV57087520; called by muse, mutect2
- OR1L1 | c.298C>T p.R100C (on ENST00000373686; = p.R50C on NM_001005236.3) | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747195797, COSV58935455; called by muse, mutect2, varscan2
- PCDHB5 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 60/632 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV50657019; called by muse, mutect2, varscan2
- PGA5 | c.657C>T p.A219= | Splice Region (SNP) | VAF 71/508 reads (14%) | catalogued as rs770670264; called by muse, mutect2, varscan2
- PHF20L1 | c.2834T>C p.L945P | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV104377892; called by muse, mutect2, varscan2
- PLXND1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV60712409; called by muse, mutect2, varscan2
- PTPRD | c.5698G>A p.A1900T | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs748481193, COSV61954145, COSV61967260; called by muse, mutect2, varscan2
- RCOR3 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1334042074, COSV65366798; called by muse, mutect2, varscan2
- SCN5A | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs199473552, CM014903; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- SLC12A4 | c.2798C>T p.S933L | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs768543789, COSV50456238; called by muse, mutect2
- STXBP1 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 41/320 reads (13%) | catalogued as CM1510222, COSV64812104; called by muse, mutect2, varscan2
- TFB2M | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63621002; called by muse, mutect2, varscan2
- THEMIS | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200529297, COSV64069470; called by muse, mutect2
- TTI2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs962681131, COSV62452498; called by muse, mutect2, varscan2
- VSTM2A | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs770082723, COSV99043277; called by muse, mutect2, varscan2
- WDR97 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1201245574; called by muse, mutect2, varscan2
- ZBTB9 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67702351; called by muse, mutect2, varscan2
- ZNF292 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.626); catalogued as rs1351503007; called by muse, mutect2
- ZNF91 | c.3332G>A p.C1111Y | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411229482; called by muse, mutect2
- ACAA2 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- ANXA10 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- BCL11A | c.2093G>A p.R698K (on ENST00000335712 / NM_001365609.1; = p.R732K on NM_018014.4) | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- BEX4 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by mutect2, varscan2
- BORCS6 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf16 | c.3395G>T p.C1132F | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C8orf48 | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2
- CABP1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CFAP58 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CHODL | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.8487T>G p.I2829M (on ENST00000297405 / NM_001363185.1; = p.I2660M on NM_052900.3) | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.5228T>A p.M1743K (on ENST00000297405 / NM_001363185.1; = p.M1639K on NM_052900.3) | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2
- CUBN | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- DTX1 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 69/543 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM186A | c.5242G>T p.E1748* | Nonsense Mutation (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- FANCL | c.740T>G p.M247R | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCHSD1 | c.1631C>A p.A544E | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSCN3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 36/463 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2
- FUBP3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GFOD2 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD3 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGB4 | c.4042A>G p.M1348V | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- KIF21B | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- KRT74 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- KRTAP8-1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- LRRC37A3 | c.4261C>T p.H1421Y | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MAP3K10 | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- MMP3 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MOSPD3 | c.692T>G p.V231G | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NDEL1 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.017); called by muse, mutect2
- NEB | c.4222C>T p.P1408S | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51D1 | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PIK3CG | c.3121dup p.Q1041Pfs*9 | Frame Shift Ins (INS) | VAF 36/368 reads (10%) | called by mutect2, pindel
- PLD5 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.745); called by muse, mutect2
- PLEKHG4 | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- POR | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- POU5F1B | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RNF112 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 67/460 reads (15%) | called by muse, mutect2, varscan2
- RP1L1 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SCYGR5 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 35/669 reads (5%) | called by muse, mutect2
- SLC4A10 | c.522T>G p.I174M | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2
- SPOCK3 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPRED3 | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 72/510 reads (14%) | called by muse, mutect2, varscan2
- SVEP1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- TAFA4 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TECTA | c.4835A>T p.E1612V | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TMEM151A | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TP53BP1 | c.5477T>C p.V1826A | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- VWF | c.2710A>G p.T904A | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WWP1 | c.850dup p.Q284Pfs*11 | Frame Shift Ins (INS) | VAF 32/301 reads (11%) | called by mutect2, pindel, varscan2
- ZBBX | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2
- ZMYND11 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ADAMTS15 | c.492C>T p.G164= | Silent (SNP) | VAF 46/492 reads (9%) | called by muse, mutect2
- APBA3 | c.198T>C p.A66= | Silent (SNP) | VAF 38/378 reads (10%) | called by muse, mutect2, varscan2
- ASMTL | c.975C>T p.A325= | Silent (SNP) | VAF 64/635 reads (10%) | called by muse, mutect2, varscan2
- CADPS | c.984C>A p.P328= | Silent (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2, varscan2
- CASP8 | c.282C>T p.G94= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV51849935; called by muse, mutect2
- CHPF | c.207G>A p.A69= | Silent (SNP) | VAF 52/534 reads (10%) | catalogued as rs1396356719; called by muse, mutect2
- COL5A3 | c.4602C>T p.P1534= | Silent (SNP) | VAF 41/443 reads (9%) | catalogued as rs1182877260; called by muse, mutect2, varscan2
- CPN1 | c.162C>T p.S54= | Silent (SNP) | VAF 37/455 reads (8%) | catalogued as rs762369560, COSV100962753; called by muse, mutect2
- DNAAF5 | c.2490C>T p.A830= | Silent (SNP) | VAF 48/397 reads (12%) | catalogued as rs774657675, COSV52416855; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDA | c.327G>A p.P109= | Silent (SNP) | VAF 57/364 reads (16%) | called by muse, mutect2, varscan2
- FAM174C | c.273G>A p.R91= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- FLRT3 | c.318A>C p.V106= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- FMOD | c.1130G>A p.*377= | Silent (SNP) | VAF 10/310 reads (3%) | called by muse, mutect2
- HCN2 | c.147C>T p.P49= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs1166485290; called by muse, mutect2
- ISYNA1 | c.651C>T p.S217= | Silent (SNP) | VAF 33/430 reads (8%) | catalogued as rs1364256420; called by muse, mutect2
- JHY | c.303C>A p.R101= | Silent (SNP) | VAF 34/298 reads (11%) | catalogued as rs150070440; called by mutect2, varscan2
- MAP3K4 | c.2025G>A p.E675= | Silent (SNP) | VAF 36/393 reads (9%) | catalogued as rs753077794; called by muse, mutect2
- NOD1 | c.2247C>T p.S749= | Silent (SNP) | VAF 37/343 reads (11%) | catalogued as rs180712416; called by muse, mutect2, varscan2
- NRROS | c.606C>T p.D202= | Silent (SNP) | VAF 54/416 reads (13%) | catalogued as rs750339010; called by muse, mutect2, varscan2
- PAGE2B | c.144T>C p.G48= | Silent (SNP) | VAF 67/200 reads (34%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.525C>T p.P175= | Silent (SNP) | VAF 38/360 reads (11%) | catalogued as rs782682819, COSV53838036; called by muse, mutect2, varscan2
- PURA | c.915G>A p.E305= | Silent (SNP) | VAF 42/316 reads (13%) | called by muse, varscan2
- RARA | c.1386G>A p.P462= | Silent (SNP) | VAF 44/313 reads (14%) | catalogued as rs776342037, COSV99564362; called by muse, mutect2, varscan2
- SCN1B | c.411C>T p.S137= | Silent (SNP) | VAF 45/426 reads (11%) | catalogued as rs202053988; called by muse, mutect2, varscan2
- SEC14L3 | c.1077C>T p.G359= | Silent (SNP) | VAF 20/225 reads (9%) | catalogued as rs372658998; called by muse, mutect2
- SEPTIN6 | c.1251G>A p.Q417= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- TADA2B | c.1020C>T p.A340= | Silent (SNP) | VAF 47/370 reads (13%) | catalogued as rs768705454, COSV53827081, COSV99380733; called by muse, mutect2, varscan2
- TMC4 | c.1314C>T p.L438= (on ENST00000617472 / NM_001145303.3; = p.L432= on NM_144686.4) | Silent (SNP) | VAF 44/389 reads (11%) | catalogued as COSV99714259; called by muse, mutect2, varscan2
- UBE2Q2 | c.361C>T p.L121= | Silent (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.1149G>A p.Q383= | Silent (SNP) | VAF 53/471 reads (11%) | catalogued as rs1034348278; called by muse, mutect2, varscan2
- XPO1 | c.801C>T p.C267= | Silent (SNP) | VAF 28/300 reads (9%) | catalogued as COSV101294331; called by muse, mutect2
- ZNF224 | c.1452C>T p.F484= | Silent (SNP) | VAF 44/416 reads (11%) | called by muse, mutect2, varscan2
- ACOT6 | c.-105G>A | 5'UTR (SNP) | VAF 50/395 reads (13%) | catalogued as rs920867024; called by muse, mutect2, varscan2
- C2orf91 | n.240C>T | RNA (SNP) | VAF 35/317 reads (11%) | called by muse, mutect2, varscan2
- CDH8 | c.*5733G>A | 3'UTR (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- HUNK | c.*1351C>A | 3'UTR (SNP) | VAF 34/392 reads (9%) | called by muse, mutect2
- LEKR1 | c.*853G>A | 3'UTR (SNP) | VAF 15/138 reads (11%) | catalogued as COSV100739502; called by muse, mutect2, varscan2
- SHF | c.304-9337C>T | Intron (SNP) | VAF 30/354 reads (8%) | called by muse, mutect2
